Surgical pathology report (de-identified scan), TCGA case TCGA-B0-4838, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-4838-01A (Primary Tumor).

FINAL DIAGNOSIS:

KIDNEY, RIGHT, LAPAROSCOPIC NEPHRECTOMY:

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR) CELL TYPE.
- B. FUHRMAN'S NUCLEAR GRADE IS 3 OF 4.
- C. THE GREATEST DIAMETER OF THE NEOPLASM IS 4.2 CM.
- D. THE NEOPLASM IS CONFINED WITHIN THE RENAL CAPSULE.
- E. NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- F. ALL SURGICAL MARGINS ARE FREE OF THE NEOPLASM.
- G. THE NON-NEOPLASTIC KIDNEY REVEALS FOCAL GLOMERULOSCLEROSIS.
- H. THE ADRENAL GLAND IS NOT SUBMITTED.
- I. TNM STAGE: pT1b NX MX.
- J. TNM HISTOLOGIC GRADE = G3.

Source: NCI Genomic Data Commons file ce1a9107-39b5-4a17-9a14-acf623700dad (TCGA-B0-4838.BF651BA3-9C72-4237-9D2E-0E7C716C36E6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).